Gene-level copy-number profile of tumor specimen AP-3336-F7 from APOLLO case AP-3336, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen AP-3336-F7: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 90b80536-89a1-4e3d-9d7d-104e81f0312a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-3336-DQ (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/4463b183-ce7c-4e6e-9708-94f084988f7b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 371; copy number 1: 8,313; copy number 2: 36,174; copy number 3: 12,521; copy number 4: 613; copy number 5: 135; copy number 6: 206; copy number 7: 45; copy number 8: 83; copy number 9: 93; copy number 10: 94; copy number 11: 14; copy number 12: 15; copy number 13: 46; copy number 14: 76; copy number 15: 4; copy number 16: 22; copy number 17: 13; copy number 18: 14; copy number 20: 16; copy number 21: 25; copy number 23: 1.

Homozygous deletions (total copy number 0; autosomes only): 163 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–71,585, 9 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5.
- chr1:89,551–91,105, 1 gene (within-gene range 0–3): AL627309.3.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr9:42,183,659–61,666,386, 48 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1, BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1, FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr14:18,333,726–19,131,167, 34 genes (within-gene range 0–1): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4, DUXAP9, AL589182.3.
- chr14:19,131,842–19,132,890, 1 gene (within-gene range 0–1): AL589182.2.
- chr15:19,878,555–19,988,117, 8 genes: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7.
- chr19:186,373–474,983, 13 genes: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P, PLPP2, MIER2, AC016588.1, THEG, AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2.
- chr21:7,744,962–9,018,670, 37 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 902 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,283,170–72,753,772, 1 gene, copy number 6 (within-gene range 2–6): AL513166.1.
- chr1:72,636,547–73,915,340, 12 genes, copy number 6: AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360, LINC02238, RNA5SP50, AL591463.1, RNU4ATAC8P.
- chr1:108,560,089–109,897,861, 56 genes, copy number 5: FAM102B, HENMT1, PRPF38B, FNDC7, AL591719.2, STXBP3, AL591719.1, AKNAD1, SPATA42, GPSM2, CLCC1, WDR47, BX679664.2, BX679664.3, BX679664.1, RANP5, TAF13, AL356488.3, TMEM167B, SCARNA2, AL356488.2, AL356488.1, C1orf194, ELAPOR1, SARS1, CELSR2, PSRC1, MYBPHL, SORT1, PSMA5, SYPL2, ATXN7L2, CYB561D1, AMIGO1, GPR61, AL355310.3, GNAI3, RNU6V, AL355310.1, MIR197, GNAT2, AMPD2, AL355310.2, RPL7P8, GSTM4, GSTM2, GSTM1, AC000032.1, GSTM5, AL158847.1, GSTM3, EPS8L3, NDUFA5P10, LINC01768, AL450468.1, AL450468.2.
- chr2:159,318,979–159,616,569, 4 genes, copy number 5 (within-gene range 3–5): BAZ2B, AC008277.1, AC008277.2, CAPZA1P2.
- chr2:159,670,708–159,904,756, 8 genes, copy number 5: AC009961.1, RPS3AP13, MARCHF7, CD302, LY75-CD302, AC009961.3, LY75, AC009961.2.
- chr2:170,640,374–171,999,859, 26 genes, copy number 5–7 (within-gene range 2–7): AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, GORASP2, TLK1, METTL8, RPS26P20, DCAF17, DAP3P2, AC007969.1, RPS15P4, CYBRD1, RPL21P38, DYNC1I2, SLC25A12, RNU6-182P, HAT1.
- chr2:172,735,274–173,486,362, 10 genes, copy number 10 (within-gene range 4–10): RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7, JPT1P1, CBY1P1, PPIAP66.
- chr2:213,284,379–214,410,501, 1 gene, copy number 6 (within-gene range 4–6): SPAG16.
- chr2:214,241,676–216,996,490, 61 genes, copy number 6 (broad region; genes not listed).
- chr6:131,780,721–133,990,432, 56 genes, copy number 5 (within-gene range 2–5): AC005587.1, MIR548H5, ENPP1, SELENOKP2, RN7SKP245, AL139805.1, AL117378.1, AL117378.2, CCN2, AL133346.1, AL021408.1, MIR548AJ1, AL021408.2, LINC01013, EEF1A1P36, MOXD1, STX7, RPL21P66, TAAR9, TAAR8, TAAR7P, TAAR6, TAAR5, TAAR4P, TAAR3P, TAAR2, TAAR1, HLFP1, VNN1, CCNG1P1, VNN3, VNN2, AL032821.1, RBM11P1, SLC18B1, RPS12, SNORD101, SNORD100, SNORA33, HMGB1P13, AL137783.1, LINC00326, RPL23AP46, AL591115.1, MTCYBP4, EYA4, AL024497.1, AL024497.2, TARID, HSPE1P21, AL450270.1, FTH1P26, LINC01312, TCF21, TBPL1, AL035699.1.
- chr6:134,897,874–135,103,056, 6 genes, copy number 5: MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1.
- chr7:79,452,877–79,654,227, 3 genes, copy number 9 (within-gene range 2–9): MAGI2-AS3, NUP35P2, RNA5SP234.
- chr7:79,912,104–79,912,208, 1 gene, copy number 9: RNU6-849P.
- chr7:80,245,926–80,318,544, 3 genes, copy number 8: RN7SL869P, AC003988.1, RN7SL35P.
- chr7:81,175,508–92,540,481, 115 genes, copy number 6–23 (within-gene range 2–23) (broad region; genes not listed).
- chr12:64,186,316–64,397,065, 8 genes, copy number 10: C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1.
- chr12:64,451,591–72,728,844, 168 genes, copy number 9–21 (broad region; genes not listed).
- chr14:28,264,390–39,216,335, 194 genes, copy number 6–16 (broad region; genes not listed).
- chr14:40,954,693–50,831,162, 128 genes, copy number 5–13 (broad region; genes not listed).
- chr19:8,778,665–9,675,100, 41 genes, copy number 6–9: AC012616.1, ZNF558, AC008734.1, MBD3L1, AC008734.2, MUC16, BOLA3P2, OR1M4P, OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3, ZNF317, OR7D2, ELOCP29, OR7E16P, OR7E25P, OR7D4, OR7D1P, OR7E24, OR7E18P, OR7E19P, OR7H1P, ZNF699, AC011451.1, ZNF559, ZNF559-ZNF177, AC011451.2, ZNF177, ZNF266, ZNF560, AC008567.2, AC008567.3, AC008567.1, ZNF426, ZNF426-DT, ZNF121, ZNF561, ZNF561-AS1, ZNF562.

Autosomal genes at a single copy (total copy number 1): 6,098. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
